Somatic mutation profile of tumor specimen TCGA-BT-A42C-01A (aliquot TCGA-BT-A42C-01A-11D-A23M-08) from TCGA case TCGA-BT-A42C, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 64.6 years (23,584 days).
Specimen TCGA-BT-A42C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb1d5120-1aed-453c-a52f-e690c763d753.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A42C-10A (Blood Derived Normal), aliquot TCGA-BT-A42C-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c91bf42d-c4cb-4133-b027-dba13b4e9d0f

The open-access MAF lists 391 somatic variants for this specimen: 296 protein-altering or splice-affecting, 87 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 87, Nonsense Mutation 19, Frame Shift Del 9, Splice Site 7, In Frame Del 4, Intron 3, 3'UTR 2, Frame Shift Ins 2, Splice Region 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8191C>T p.Q2731* | Nonsense Mutation (SNP) | VAF 54/88 reads (61%) | catalogued as rs397507966, CM107510, COSV66449420; ClinVar: not provided / pathogenic; called by muse, varscan2
- FGFR3 | c.*174A>G | 3'UTR (SNP) | VAF 179/255 reads (70%) | catalogued as rs121913485, CM960657, COSV53390174; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.2667G>A p.G889= | Splice Region (SNP) | VAF 59/176 reads (34%) | catalogued as COSV55589094; called by muse, mutect2, varscan2
- ABCD3 | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs1557679774, COSV59865950; called by muse, mutect2, varscan2
- ABCG1 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV59203273; called by muse, mutect2
- AC011462.1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as rs1298823471, COSV54196723; called by muse, mutect2, varscan2
- ACAD11 | c.1406A>G p.Q469R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53895557; called by muse, mutect2, varscan2
- ACIN1 | c.2736C>A p.D912E | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.969); catalogued as COSV52975505; called by muse, mutect2
- ACOX2 | c.524C>A p.T175N | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV57148621; called by muse, mutect2
- ACTN3 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV72207571; called by muse, mutect2
- ADGRG1 | c.712T>C p.W238R | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV65635519; called by muse, mutect2, varscan2
- ADRB1 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.948); catalogued as COSV65167798; called by muse, mutect2, varscan2
- AIDA | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs757636166, COSV60663652; called by muse, mutect2, varscan2
- AMOTL1 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV54415157; called by muse, mutect2, varscan2
- AP2B1 | c.1541C>A p.S514Y | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51997209; called by muse, mutect2
- AP3D1 | c.3438G>A p.M1146I | Missense Mutation (SNP) | VAF 160/335 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61427117; called by muse, mutect2, varscan2
- ARHGAP30 | c.1151C>G p.S384C | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV63516009; called by muse, mutect2, varscan2
- ASXL1 | c.3184C>T p.P1062S | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs776213974, COSV60106723; called by muse, mutect2, varscan2
- ATP12A | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs992979300, COSV54515124, COSV54516652; called by muse, mutect2, varscan2
- B4GALNT4 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs779965005, COSV57322909; called by muse, mutect2, varscan2
- BAZ2B | c.2872G>C p.E958Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV54275369; called by muse, mutect2, varscan2
- BLNK | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56410464, COSV99813929; called by muse, mutect2, varscan2
- BRCA2 | c.8257C>T p.L2753F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV66452544; called by muse, varscan2
- BRIP1 | c.1920C>G p.I640M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV51998263, COSV99370948; called by muse, mutect2, varscan2
- BTF3 | c.343G>A p.V115M (on ENST00000380591 / NM_001037637.1; = p.V71M on NM_001207.4) | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100246605, COSV60063368; called by muse, mutect2, varscan2
- BTG4 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV63635609; called by muse, mutect2, varscan2
- BUB1 | c.2626-2A>G p.X876_splice | Splice Site (SNP) | VAF 41/153 reads (27%) | catalogued as COSV57063014; called by muse, mutect2, varscan2
- C1QTNF7 | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54852167; called by muse, mutect2
- C1orf54 | c.84T>A p.D28E | Missense Mutation (SNP) | VAF 34/379 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs1553851898, COSV64257431; called by muse, mutect2
- CACNA2D1 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV62377810; called by muse, mutect2, varscan2
- CASKIN2 | c.3115C>G p.P1039A | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58595038; called by muse, mutect2
- CBX4 | c.583C>G p.P195A | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs1262389954, COSV53965298; called by muse, mutect2, varscan2
- CCDC17 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59646853; called by muse, mutect2, varscan2
- CCDC74A | c.891G>C p.K297N | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54606274; called by muse, mutect2
- CCDC77 | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV53472678; called by muse, mutect2
- CCDC97 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757960060, COSV54190095; called by muse, mutect2, varscan2
- CDH18 | c.1904C>T p.T635I | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV56916827; called by muse, mutect2
- CFAP36 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV59117436, COSV59119596; called by muse, mutect2
- CORO1C | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54595443; called by muse, mutect2
- CRACDL | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV67407720; called by muse, mutect2, varscan2
- CSNK2A1 | c.809A>G p.N270S | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs375633788; called by muse, mutect2, varscan2
- CUBN | c.3128G>A p.S1043N | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64714069; called by muse, mutect2, varscan2
- CYP2C18 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV53669563; called by muse, mutect2
- DAP3 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.429); catalogued as rs1452874782, COSV58020232; called by muse, mutect2
- DCDC2 | c.995A>T p.D332V | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65828626; called by muse, mutect2
- DCT | c.378T>G p.I126M | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs933213657, COSV65468717; called by muse, mutect2, varscan2
- DDX46 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV62799121; called by muse, mutect2, varscan2
- DFFA | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65477352; called by muse, mutect2, varscan2
- DLC1 | c.2212A>T p.T738S (on ENST00000276297 / NM_001348081.2; = p.T301S on NM_006094.5) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.178); catalogued as rs1443823431, COSV52300341; called by muse, mutect2, varscan2
- DMRTA1 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV57925502; called by muse, mutect2, varscan2
- DNAAF1 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as rs1326170007, COSV57577034; called by muse, mutect2, varscan2
- DNAH2 | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV50014102; called by muse, mutect2, varscan2
- DPPA2 | c.439T>G p.S147A | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.457); catalogued as COSV72118032; called by muse, mutect2, varscan2
- DPYSL2 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 5/100 reads (5%) | catalogued as COSV100233879; called by muse, mutect2
- DRG2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs770854583, COSV56728179; called by muse, mutect2, varscan2
- DYRK4 | c.1379T>C p.V460A | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV50538807; called by muse, mutect2, varscan2
- EDC3 | c.365A>C p.D122A | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1022854363, COSV59339924; called by muse, mutect2
- EDNRA | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV60097086; called by muse, mutect2, varscan2
- EEF2K | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.024); catalogued as COSV53780985; called by muse, mutect2, varscan2
- EFCAB5 | c.3907T>G p.S1303A | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); catalogued as COSV57928748; called by muse, mutect2, varscan2
- EFCAB6 | c.3584C>A p.T1195N | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53061874; called by muse, mutect2, varscan2
- EFS | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs1448487278, COSV53731994; called by muse, mutect2, varscan2
- EHBP1L1 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV58572535; called by muse, mutect2, varscan2
- EIF2AK1 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV52238585; called by muse, mutect2
- EP400 | c.4400G>A p.R1467Q | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV57769992; called by muse, mutect2, varscan2
- ERMN | c.509T>C p.M170T | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.163); catalogued as rs771950532, COSV68075225; called by muse, mutect2, varscan2
- ETAA1 | c.780G>C p.K260N | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV55472765; called by muse, mutect2, varscan2
- ETNPPL | c.1465A>C p.T489P | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as COSV56595542; called by muse, mutect2, varscan2
- EXOC7 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV58741246; called by muse, mutect2
- FAM241B | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV64768218; called by muse, mutect2
- FAU | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.273); catalogued as rs1171332301, COSV54194271, COSV99658058; called by muse, mutect2
- FBN2 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV52508196; called by muse, mutect2, varscan2
- FBXO46 | c.221C>G p.S74* | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | catalogued as COSV58347688; called by muse, mutect2, varscan2
- FCN3 | c.309G>C p.L103F | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54641147; called by muse, mutect2, varscan2
- FLG | c.7436A>C p.E2479A | Missense Mutation (SNP) | VAF 108/1460 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.055); catalogued as COSV64240667; called by muse, mutect2
- FMN2 | c.3029C>T p.P1010L | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.834); catalogued as rs756426957, COSV60421264, COSV60426866; called by muse, varscan2
- FUT1 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.169); catalogued as COSV55810204; called by muse, mutect2, varscan2
- GAL3ST4 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.103); catalogued as COSV57586103; called by muse, mutect2, varscan2
- GAS8 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as COSV51943179; called by muse, mutect2
- GGCX | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 105/231 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs1187060620, COSV52088006; called by muse, mutect2, varscan2
- GLI3 | c.3110C>T p.T1037M | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.223); catalogued as rs769100742, COSV67887658; called by muse, mutect2, varscan2
- GMEB1 | c.1384A>C p.T462P | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53794078; called by muse, mutect2, varscan2
- GNL3 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56477306; called by muse, mutect2, varscan2
- GRIN2B | c.2732T>G p.L911R | Missense Mutation (SNP) | VAF 71/362 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV74205639; called by muse, mutect2, varscan2
- GRM3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV64470689; called by muse, mutect2
- GRM5 | c.977C>G p.T326R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59602052; called by muse, mutect2, varscan2
- GSDMD | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV52797020; called by muse, mutect2
- HEPH | c.2393G>A p.R798Q (on ENST00000343002; = p.R531Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs758208170, COSV57959147; called by muse, mutect2, varscan2
- HMCN1 | c.12581G>C p.G4194A | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54894709; called by muse, mutect2, varscan2
- HSDL2 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV52714594, COSV52717241; called by muse, mutect2, varscan2
- HTR1B | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 74/115 reads (64%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs968574182, COSV64051119; called by muse, mutect2, varscan2
- HYDIN | c.4829G>T p.R1610L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99992890; called by muse, mutect2, varscan2
- IGHMBP2 | c.1778A>G p.E593G | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54821857; called by muse, mutect2
- IGSF11 | c.728T>C p.I243T (on ENST00000393775 / NM_001015887.3; = p.I242T on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773629427, COSV61168763; called by muse, mutect2, varscan2
- ING2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV56564106; called by muse, mutect2, varscan2
- INSIG2 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV55522399, COSV55523163; called by muse, mutect2, varscan2
- IQCG | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 13/432 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1403853760, COSV54561723, COSV54565236; called by muse, mutect2
- IRAK3 | c.1307T>C p.M436T | Missense Mutation (SNP) | VAF 84/497 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV54161177; called by muse, mutect2, varscan2
- ITGA3 | c.2534C>A p.P845H | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV50309161; called by muse, mutect2
- IYD | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.655); catalogued as COSV57600641; called by muse, mutect2, varscan2
- KCNA2 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV60369144; called by muse, mutect2, varscan2
- KCND1 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54413714, COSV54415974; called by muse, mutect2, varscan2
- KCNT1 | c.797G>A p.G266E (on ENST00000488444; = p.G285E on NM_020822.3) | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV53700058; called by muse, mutect2, varscan2
- KCTD3 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52066093; called by muse, mutect2
- KIAA0513 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50741049; called by muse, mutect2
- KIAA0513 | c.908C>G p.T303S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV50741057; called by muse, mutect2, varscan2
- KIF2B | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 95/329 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs746185699, COSV52129583; called by muse, mutect2, varscan2
- KIF6 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV54675055; called by muse, mutect2
- KLF5 | c.1067C>G p.P356R | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV66614198; called by muse, mutect2, varscan2
- KLHL20 | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52939969, COSV52942037; called by muse, mutect2, varscan2
- KMT2D | c.9614G>T p.G3205V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV56453125; called by muse, mutect2
- KNL1 | c.889A>T p.T297S (on ENST00000346991 / NM_170589.5; = p.T271S on NM_144508.5) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61153770; called by mutect2, varscan2
- KNTC1 | c.3832T>G p.S1278A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV61079784; called by muse, mutect2
- LAMA1 | c.5224G>A p.E1742K | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as COSV67535764; called by muse, mutect2, varscan2
- LCT | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.511); catalogued as COSV51547667; called by muse, mutect2
- LGALS4 | c.657G>C p.K219N | Missense Mutation (SNP) | VAF 187/323 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV57043512; called by muse, mutect2, varscan2
- LHFPL5 | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 331/506 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV64177610; called by muse, mutect2, varscan2
- LOXL3 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.671); catalogued as rs1271526877, COSV51207111; called by muse, mutect2, varscan2
- LRIT1 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs75121307, COSV64512446; called by muse, mutect2, varscan2
- LRP1B | c.12218C>T p.P4073L | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67209139; called by muse, varscan2
- LRRC37A3 | c.2213C>G p.S738C | Missense Mutation (SNP) | VAF 64/472 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV59761063, COSV59761436; called by muse, mutect2, varscan2
- LRRC41 | c.2266C>A p.L756M | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58439745; called by muse, mutect2, varscan2
- LUZP1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV56500540; called by muse, mutect2, varscan2
- LUZP1 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.586); catalogued as COSV56500549; called by muse, mutect2, varscan2
- MAG | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.689); catalogued as rs768876800, COSV100727515, COSV62700176, COSV62702060; called by muse, mutect2, varscan2
- MAMSTR | c.386C>G p.S129C (on ENST00000318083 / NM_001130915.2; = p.S26C on NM_182574.2) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs1404299736; called by muse, mutect2
- MATN4 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 52/130 reads (40%) | PolyPhen probably damaging (0.999); catalogued as rs939059210, COSV59213375; called by muse, mutect2, varscan2
- MDGA2 | c.1657G>C p.V553L (on ENST00000399232 / NM_001113498.2; = p.V255L on NM_182830.4) | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.025); catalogued as COSV62088259, COSV62090612; called by muse, mutect2, varscan2
- MDH1B | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV65588920, COSV65589344; called by muse, mutect2, varscan2
- MFHAS1 | c.1798G>C p.D600H | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV52281502; called by muse, mutect2
- MGA | c.2738C>T p.S913L | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as COSV54952539; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1412G>T p.R471I | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV56618850; called by muse, mutect2, varscan2
- MS4A14 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.709); catalogued as COSV55734387; called by muse, mutect2, varscan2
- MSH6 | c.2638G>T p.D880Y | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV52278215; called by muse, mutect2, varscan2
- MTUS1 | c.1448C>G p.T483R | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as COSV50554883; called by muse, mutect2, varscan2
- MUC16 | c.37263G>T p.Q12421H | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV67461416; called by muse, mutect2
- MUC17 | c.8263A>T p.S2755C | Missense Mutation (SNP) | VAF 23/720 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV60286477; called by muse, mutect2
- MUC17 | c.12796G>A p.D4266N | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.094); catalogued as COSV60286483; called by muse, mutect2, varscan2
- MYH1 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 118/365 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV99875948; called by muse, mutect2, varscan2
- MYT1 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762983260, COSV60502382; called by muse, mutect2
- NAIP | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52001115; called by muse, mutect2, varscan2
- NBR1 | c.2462del p.L821Rfs*43 | Frame Shift Del (DEL) | VAF 37/134 reads (28%) | catalogued as COSV57831997; called by mutect2, pindel, varscan2
- NCAN | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV53050098; called by muse, mutect2, varscan2
- NGFR | c.1177C>A p.Q393K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50802037; called by muse, varscan2
- NGFR | c.1245G>C p.E415D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); catalogued as COSV50802046; called by muse, varscan2
- NOS2 | c.3050G>A p.R1017H | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs371294348, COSV58223278; called by muse, mutect2, varscan2
- NPAS4 | c.328-1G>A p.X110_splice | Splice Site (SNP) | VAF 67/294 reads (23%) | catalogued as COSV60650049; called by muse, mutect2, varscan2
- NPRL3 | c.523G>A p.D175N (on ENST00000611875 / NM_001077350.3; = p.D150N on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV67852738; called by muse, mutect2, varscan2
- NT5C3B | c.181A>T p.N61Y | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53172992; called by muse, mutect2, varscan2
- NYAP2 | c.1204G>C p.G402R | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.868); catalogued as COSV56003448, COSV56004119; called by muse, mutect2, varscan2
- OGDH | c.1834G>T p.D612Y | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV56048779; called by muse, mutect2, varscan2
- OR2B2 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57579492; called by muse, mutect2, varscan2
- OR2D3 | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV53492684; called by muse, mutect2, varscan2
- OR8H2 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 38/750 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.378); catalogued as COSV57944266; called by muse, mutect2
- ORAI3 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV52686984; called by muse, mutect2
- P3H1 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.368); catalogued as COSV52533136; called by muse, mutect2, varscan2
- PCDHA12 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV56495050; called by muse, mutect2, varscan2
- PCDHA3 | c.213C>A p.H71Q | Missense Mutation (SNP) | VAF 65/437 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.048); catalogued as COSV65366172; called by muse, mutect2, varscan2
- PCLO | c.3999A>T p.E1333D | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as COSV61629837; called by muse, mutect2, varscan2
- PCSK4 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV56298941, COSV56298999; called by muse, mutect2, varscan2
- PDZD4 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 75/92 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1557077191, COSV51246328; called by muse, mutect2, varscan2
- PER3 | c.1091G>T p.S364I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV62705459; called by muse, mutect2, varscan2
- PI4K2A | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs1427364383, COSV65701312; called by muse, mutect2, varscan2
- PIAS4 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs1568223334, COSV53678822; called by muse, mutect2, varscan2
- PIEZO2 | c.8155G>A p.E2719K | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53288482; called by muse, mutect2, varscan2
- PITPNM1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs933400579, COSV56873366; called by muse, mutect2, varscan2
- PITPNM1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758966879, COSV56873531; called by muse, mutect2, varscan2
- PKP4 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV67676788; called by muse, mutect2
- PLCB4 | c.2057C>T p.T686I | Missense Mutation (SNP) | VAF 26/353 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as rs749000875, COSV53799364; called by muse, mutect2
- PLPP1 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53304642; called by muse, mutect2
- PLXDC1 | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59550711; called by muse, mutect2, varscan2
- PMS1 | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs770544182, COSV59715870, COSV59715975; called by muse, mutect2, varscan2
- PNLIPRP1 | c.605G>T p.S202I | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV62611519; called by muse, mutect2, varscan2
- PNN | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as COSV53766090; called by muse, mutect2, varscan2
- PODN | c.1282C>A p.R428S (on ENST00000395871; = p.R380S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV57012790; called by muse, mutect2, varscan2
- PPP1R11 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 35/222 reads (16%) | catalogued as COSV99748746; called by muse, mutect2, varscan2
- PPP1R18 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); catalogued as COSV51295436; called by muse, mutect2
- PRDX1 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as rs1309588088, COSV53113482; called by muse, mutect2, varscan2
- PRICKLE4 | c.674C>T p.T225I (on ENST00000359201; = p.T265I on NM_013397.6) | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV59254759; called by muse, mutect2
- PSG7 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68444880; called by muse, mutect2, varscan2
- PTPN4 | c.2661G>A p.M887I | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV55300598; called by muse, mutect2, varscan2
- PWWP3A | c.1751A>G p.K584R (on ENST00000627377; = p.K583R on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.051); catalogued as rs201308121; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs763900222, COSV54759489; called by muse, mutect2, varscan2
- RAB6B | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 77/145 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV53313111; called by muse, mutect2, varscan2
- RAPGEF2 | c.3344C>G p.S1115C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52427116; called by muse, mutect2, varscan2
- RASA3 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs986093149, COSV61866365, COSV61872104; called by muse, mutect2, varscan2
- RASGRF2 | c.2204G>T p.R735I | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV54128091; called by muse, mutect2, varscan2
- RELN | c.5636C>G p.S1879C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV58998126; called by mutect2, varscan2
- RERE | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61938720; called by muse, mutect2, varscan2
- RGS22 | c.1261T>C p.F421L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62660792; called by muse, mutect2, varscan2
- RNF43 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV68457755; called by muse, mutect2, varscan2
- ROBO3 | c.3023G>A p.R1008K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1164429066; called by muse, mutect2
- RPGR | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as COSV58834530; called by muse, mutect2, varscan2
- RPUSD2 | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV59765326; called by muse, mutect2, varscan2
- RSPRY1 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV101070973, COSV68027577; called by muse, mutect2, varscan2
- RYR3 | c.9764C>T p.A3255V (on ENST00000389232; = p.A3256V on NM_001036.6) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs775224723, COSV66785710; called by muse, mutect2, varscan2
- S100PBP | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs773253154, COSV65110613; called by muse, mutect2, varscan2
- SCN2A | c.4006T>A p.S1336T | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51838752; called by muse, mutect2
- SCN4A | c.3948G>T p.Q1316H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71126541; called by muse, mutect2, varscan2
- SEC14L1 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66721905; called by muse, mutect2
- SETD1A | c.3785C>A p.T1262N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV52686998; called by muse, mutect2, varscan2
- SGIP1 | c.1490T>C p.I497T | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.395); catalogued as rs779853610, COSV52763505; called by muse, mutect2
- SIDT1 | c.855G>C p.W285C | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.957); catalogued as COSV53500528; called by muse, mutect2, varscan2
- SLC17A3 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 79/129 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV62342051; called by muse, mutect2, varscan2
- SLC25A19 | c.170C>G p.A57G | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as COSV57467490; called by muse, mutect2
- SLC27A2 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as COSV51059067; called by muse, mutect2
- SLC6A12 | c.959T>G p.I320S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62884874; called by muse, mutect2
- SLC6A9 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV62210429; called by muse, mutect2, varscan2
- SMPD3 | c.434T>A p.F145Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV54711745; called by muse, mutect2, varscan2
- SOX5 | c.345A>T p.E115D | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV58627164; called by muse, mutect2
- SPATA4 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV54589645; called by muse, mutect2, varscan2
- SPEN | c.757C>G p.Q253E | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV65360144, COSV65360892; called by muse, varscan2
- SPTAN1 | c.3304G>T p.E1102* | Nonsense Mutation (SNP) | VAF 51/92 reads (55%) | catalogued as COSV63988543; called by muse, varscan2
- SPTAN1 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as rs1272083363, COSV63986657; called by muse, mutect2, varscan2
- SPTAN1 | c.3739G>C p.E1247Q | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV63986658; called by muse, mutect2, varscan2
- SPTAN1 | c.5323G>A p.D1775N | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV63986660; called by muse, mutect2, varscan2
- SPTAN1 | c.7096G>A p.E2366K | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV63985337; called by muse, mutect2, varscan2
- SRFBP1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV59582591; called by muse, mutect2, varscan2
- STOML2 | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.355); catalogued as COSV59715759; called by muse, mutect2, varscan2
- SYNPO2 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as COSV61109714; called by muse, mutect2, varscan2
- SYT9 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59617263; called by muse, mutect2, varscan2
- TBC1D9 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as COSV101464362, COSV71307311; called by muse, mutect2, varscan2
- TCN2 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs778691896, COSV53191193; called by muse, mutect2, varscan2
- THADA | c.682T>C p.C228R | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV57681975; called by muse, mutect2
- THBS3 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64249106; called by muse, mutect2, varscan2
- THPO | c.1187G>T p.G396V (on ENST00000649095 / NM_001290003.1; = p.G256V on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/391 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV52615558, COSV52615933; called by muse, mutect2, varscan2
- TIAM2 | c.827G>T p.S276I | Missense Mutation (SNP) | VAF 71/103 reads (69%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); catalogued as COSV59693083; called by muse, mutect2, varscan2
- TIE1 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV65249342; called by muse, mutect2
- TMPRSS11E | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59518790; called by muse, mutect2, varscan2
- TNPO2 | c.1427A>G p.K476R | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV63508116; called by muse, mutect2
- TNR | c.2049G>C p.R683S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as COSV54881565; called by muse, mutect2, varscan2
- TREM2 | c.547T>A p.F183I | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58294354; called by muse, mutect2
- TSEN2 | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53188529; called by muse, mutect2, varscan2
- TSPAN2 | c.468C>G p.S156R | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as COSV65689904; called by muse, mutect2
- TTN | c.85180C>T p.R28394C (on ENST00000591111; = p.R20970C on NM_003319.4) | Missense Mutation (SNP) | VAF 11/117 reads (9%) | PolyPhen possibly damaging (0.862); catalogued as rs397517747, COSV60002845; ClinVar: uncertain significance; called by muse, mutect2
- TXNDC5 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65730335; called by muse, mutect2, varscan2
- UNC79 | c.1267C>T p.H423Y (on ENST00000393151 / NM_001346218.2; = p.H246Y on NM_020818.5) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV56384021; called by muse, mutect2, varscan2
- USP1 | c.2232G>C p.E744D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV52003024; called by muse, mutect2, varscan2
- USP21 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57087996; called by muse, mutect2
- VNN1 | c.725T>C p.L242S | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1273975444, COSV63389744; called by muse, mutect2, varscan2
- VRTN | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV56440480; called by muse, mutect2
- VWCE | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.159); catalogued as COSV57111970; called by muse, mutect2, varscan2
- WDR82 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56601523; called by muse, mutect2, varscan2
- WNK1 | c.4909G>A p.E1637K (on ENST00000315939 / NM_018979.4; = p.E1390K on NM_014823.3) | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV60031363; called by muse, varscan2
- WNK1 | c.4993G>A p.E1665K (on ENST00000315939 / NM_018979.4; = p.E1418K on NM_014823.3) | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV60031403; called by muse, varscan2
- XYLT1 | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54482662; called by muse, mutect2
- ZBED8 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs1290453215, COSV68824649; called by muse, mutect2, varscan2
- ZIC4 | c.562A>C p.K188Q | Missense Mutation (SNP) | VAF 36/455 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67171381; called by muse, mutect2
- ZNF257 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV71306954; called by muse, mutect2, varscan2
- ZNF460 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV64415570; called by muse, mutect2, varscan2
- ZNF471 | c.1609C>G p.H537D | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57290962; called by muse, mutect2
- ZNF598 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV70910436; called by muse, mutect2
- ZNF682 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.909); catalogued as rs1308478945, COSV62066768; called by muse, mutect2, varscan2
- ZNF683 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.483); catalogued as COSV62874037; called by muse, mutect2, varscan2
- ZNF93 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59373710, COSV59375251, COSV59379368; called by muse, mutect2, varscan2
- ZSCAN9 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV52849581; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1816G>T p.E606* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- ADRM1 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2
- AP1B1 | c.1437+1_1437+9del p.X479_splice | Splice Site (DEL) | VAF 13/112 reads (12%) | called by mutect2, pindel, varscan2
- ARMC3 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- BTAF1 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- C20orf194 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 37/161 reads (23%) | called by muse, mutect2, varscan2
- CCDC57 | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CDKN1A | c.7dup p.E3Gfs*33 | Frame Shift Ins (INS) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- CLHC1 | c.1281C>A p.Y427* | Nonsense Mutation (SNP) | VAF 50/129 reads (39%) | called by muse, mutect2, varscan2
- CLTC | c.4900_4903+10delinsATGGTAA p.X1634_splice | Splice Site (DEL) | VAF 19/77 reads (25%) | called by pindel, varscan2*
- DCAF4L1 | c.659C>G p.S220* | Nonsense Mutation (SNP) | VAF 79/377 reads (21%) | called by muse, mutect2, varscan2
- DSE | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 55/186 reads (30%) | called by muse, mutect2, varscan2
- EDEM2 | c.796A>T p.K266* | Nonsense Mutation (SNP) | VAF 42/416 reads (10%) | called by muse, mutect2, varscan2
- FAM110C | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- GNA13 | c.813_824del p.F272_I275del | In Frame Del (DEL) | VAF 22/214 reads (10%) | called by mutect2, pindel
- GTF2I | c.238+1_238+29del p.X80_splice | Splice Site (DEL) | VAF 22/108 reads (20%) | called by mutect2, pindel
- HMCN1 | c.14450G>A p.W4817* | Nonsense Mutation (SNP) | VAF 65/147 reads (44%) | called by muse, mutect2, varscan2
- IFNG | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- IGHA1 | c.891A>G p.I297M | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.116); called by muse, mutect2
- IGHV7-81 | c.350G>C p.R117T | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- JPH4 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- KDM4B | c.1759_1774del p.T587Efs*12 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- KIF20B | c.4632_4638del p.D1544Efs*5 (on ENST00000371728 / NM_001284259.2; = p.D1504Efs*5 on NM_016195.4) | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- KIF21A | c.4553_4554insAAGTATGTATA p.Y1518* (on ENST00000361418 / NM_001378440.1; = p.Y1505* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- MDC1 | c.5572dup p.T1858Nfs*30 | Frame Shift Ins (INS) | VAF 174/390 reads (45%) | called by mutect2, pindel, varscan2
- MECOM | c.1748_1753del p.Q583_P584del (on ENST00000468789 / NM_001105078.4; = p.Q771_P772del on NM_004991.4) | In Frame Del (DEL) | VAF 10/110 reads (9%) | called by mutect2, pindel
- PCDHGA7 | c.1327del p.A443Qfs*31 | Frame Shift Del (DEL) | VAF 13/124 reads (10%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.9001C>T p.Q3001* | Nonsense Mutation (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- PLCH1 | c.2272-1G>C p.X758_splice (on ENST00000340059 / NM_001130960.2; = p.X770_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- PLXNA4 | c.5303_5317del p.D1768_S1772del | In Frame Del (DEL) | VAF 19/190 reads (10%) | called by mutect2, pindel
- PRELID3B | c.196_201+7del p.X66_splice | Splice Site (DEL) | VAF 33/220 reads (15%) | called by mutect2, pindel, varscan2
- RAD21 | c.1417_1445del p.P473Nfs*2 | Frame Shift Del (DEL) | VAF 18/186 reads (10%) | called by mutect2, pindel
- RPL23 | c.191_210del p.T64Rfs*20 | Frame Shift Del (DEL) | VAF 20/154 reads (13%) | called by mutect2, pindel
- SLC10A1 | c.540del p.P181Hfs*12 | Frame Shift Del (DEL) | VAF 32/145 reads (22%) | called by mutect2, pindel, varscan2
- SPEN | c.7390_7398del p.D2464_S2466del | In Frame Del (DEL) | VAF 12/136 reads (9%) | called by mutect2, pindel
- TOX4 | c.1590_1618del p.E530Dfs*8 | Frame Shift Del (DEL) | VAF 11/157 reads (7%) | called by mutect2, pindel
- TSC1 | c.132del p.L45Wfs*17 | Frame Shift Del (DEL) | VAF 29/50 reads (58%) | called by mutect2, pindel, varscan2
- UCP1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 30/177 reads (17%) | called by muse, mutect2, varscan2
- USP34 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- XAGE2 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 124/146 reads (85%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ZYG11B | c.2076A>C p.E692D | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.365); called by muse, mutect2
- AKAP8L | c.663C>G p.L221= | Silent (SNP) | VAF 92/192 reads (48%) | catalogued as COSV68473259; called by muse, mutect2, varscan2
- ARHGAP25 | c.66G>T p.R22= (on ENST00000409202 / NM_001007231.3; = p.R15= on NM_014882.3) | Silent (SNP) | VAF 52/757 reads (7%) | catalogued as COSV54901491; called by muse, mutect2
- ASAP3 | c.1533C>T p.P511= | Silent (SNP) | VAF 66/144 reads (46%) | catalogued as COSV60874239; called by muse, mutect2, varscan2
- ATF7IP2 | c.1398G>A p.L466= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV61093210; called by muse, mutect2, varscan2
- ATP12A | c.1908C>A p.P636= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as COSV54515102; called by muse, mutect2
- C1orf127 | c.615G>A p.L205= | Silent (SNP) | VAF 68/161 reads (42%) | catalogued as COSV65437066; called by muse, mutect2, varscan2
- CAMTA1 | c.1095G>A p.G365= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs1263397755, COSV57896275; called by muse, mutect2
- CARD11 | c.870G>A p.G290= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV67798551; called by muse, mutect2, varscan2
- CARD14 | c.687G>C p.L229= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV60123015; called by muse, mutect2, varscan2
- CCDC148 | c.1393T>C p.L465= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs763028313, COSV51758917; called by muse, mutect2, varscan2
- CCDC87 | c.1338A>T p.V446= | Silent (SNP) | VAF 17/306 reads (6%) | catalogued as COSV59578826; called by muse, mutect2
- CCHCR1 | c.2208C>G p.T736= | Silent (SNP) | VAF 80/1030 reads (8%) | catalogued as COSV52535367; called by muse, mutect2
- CFAP221 | c.1548G>C p.R516= | Silent (SNP) | VAF 32/289 reads (11%) | catalogued as COSV54656634; called by muse, mutect2, varscan2
- DAXX | c.309G>A p.A103= | Silent (SNP) | VAF 11/332 reads (3%) | catalogued as rs1159001466, COSV56468569; called by muse, mutect2
- DCST1 | c.1440C>T p.L480= | Silent (SNP) | VAF 17/229 reads (7%) | catalogued as COSV55058704; called by muse, mutect2
- DGKG | c.222C>T p.H74= | Silent (SNP) | VAF 34/260 reads (13%) | catalogued as rs750121479, COSV53963993; called by muse, mutect2, varscan2
- DLC1 | c.1782C>T p.V594= (on ENST00000276297 / NM_001348081.2; = p.V157= on NM_006094.5) | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV52300355; called by muse, mutect2, varscan2
- DLGAP3 | c.1113G>A p.P371= | Silent (SNP) | VAF 18/225 reads (8%) | catalogued as rs139408471; called by muse, mutect2
- DNAH1 | c.5346C>G p.L1782= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV70228347; called by muse, mutect2, varscan2
- DNAH3 | c.1464C>T p.I488= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs1201076538, COSV54517096; called by muse, mutect2, varscan2
- DPF1 | c.394C>T p.L132= | Silent (SNP) | VAF 42/341 reads (12%) | catalogued as COSV62792574; called by muse, mutect2, varscan2
- DYNC2I2 | c.1026C>T p.F342= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as COSV63986663; called by muse, mutect2, varscan2
- EFL1 | c.2802C>T p.C934= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs199710903, COSV51604876; called by muse, mutect2
- EIF2D | c.300T>G p.P100= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV55113314; called by muse, mutect2, varscan2
- EMILIN2 | c.1749G>A p.L583= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as COSV54422918; called by muse, mutect2
- EPB41L4B | c.1830T>C p.C610= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as COSV65802856; called by muse, mutect2, varscan2
- ERBB3 | c.501G>C p.V167= | Silent (SNP) | VAF 33/306 reads (11%) | catalogued as COSV57251363; called by muse, mutect2, varscan2
- FOXP1 | c.1017C>A p.A339= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV59540639; called by muse, mutect2, varscan2
- GABRB1 | c.84C>T p.T28= | Silent (SNP) | VAF 25/326 reads (8%) | catalogued as rs1415580816, COSV54978895; called by muse, mutect2
- GLI2 | c.3462G>C p.L1154= (on ENST00000361492 / NM_001374353.1; = p.L1171= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV58040101; called by muse, mutect2
- GLI3 | c.3558G>T p.P1186= | Silent (SNP) | VAF 99/298 reads (33%) | catalogued as COSV67887656, COSV67892960; called by muse, mutect2, varscan2
- GP1BA | c.540C>T p.P180= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs1275586054, COSV56699077; called by muse, mutect2, varscan2
- GPR45 | c.1014G>A p.L338= | Silent (SNP) | VAF 21/240 reads (9%) | catalogued as COSV51523501; called by muse, mutect2
- GRAMD1B | c.1494C>G p.V498= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV59203136; called by muse, mutect2, varscan2
- GTF2H3 | c.801C>A p.V267= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV57458617; called by muse, mutect2, varscan2
- HERC1 | c.3471T>G p.L1157= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV71247376, COSV71248864; called by muse, varscan2
- HOMER1 | c.897A>G p.K299= | Silent (SNP) | VAF 47/114 reads (41%) | catalogued as COSV56525762; called by muse, mutect2, varscan2
- IL12RB1 | c.1551G>A p.T517= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs760657739, COSV74045465, COSV74045561; called by muse, mutect2, varscan2
- ITGA10 | c.1686T>C p.D562= | Silent (SNP) | VAF 42/574 reads (7%) | catalogued as COSV65197044; called by muse, mutect2
- KALRN | c.8325G>A p.L2775= (on ENST00000360013 / NM_001024660.4; = p.L1078= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 75/165 reads (45%) | catalogued as COSV52254908; called by muse, mutect2, varscan2
- KCNH6 | c.501G>A p.G167= | Silent (SNP) | VAF 31/221 reads (14%) | catalogued as COSV59002749; called by muse, mutect2, varscan2
- KLHL8 | c.1194A>C p.S398= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV56747561; called by muse, mutect2, varscan2
- KMT2D | c.9615A>G p.G3205= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99981843; called by muse, mutect2
- KNTC1 | c.4332A>C p.T1444= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV61079785; called by muse, mutect2, varscan2
- LRP1B | c.10689T>G p.G3563= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as COSV67209143; called by muse, mutect2
- LYST | c.9471C>T p.F3157= | Silent (SNP) | VAF 40/158 reads (25%) | catalogued as COSV67706284; called by muse, mutect2, varscan2
- METAP1D | c.966G>A p.S322= | Silent (SNP) | VAF 289/476 reads (61%) | catalogued as COSV59929823; called by muse, mutect2, varscan2
- MGAT5B | c.1593C>T p.I531= (on ENST00000569840 / NM_001199172.2; = p.I529= on NM_144677.3) | Silent (SNP) | VAF 96/302 reads (32%) | catalogued as rs766733616, COSV56928315; called by muse, mutect2, varscan2
- MPP2 | c.414C>G p.T138= (on ENST00000461854 / NM_001278372.2; = p.T114= on NM_005374.5) | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- N6AMT1 | c.177A>G p.V59= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs757926146, COSV58134247; called by muse, mutect2, varscan2
- NBPF11 | c.2307C>T p.L769= | Silent (SNP) | VAF 75/316 reads (24%) | called by muse, mutect2, varscan2
- NEURL4 | c.3681C>G p.L1227= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV59748972; called by muse, mutect2, varscan2
- NIN | c.39C>G p.L13= | Silent (SNP) | VAF 162/490 reads (33%) | catalogued as rs1470624113, COSV55387871; called by muse, mutect2, varscan2
- NRXN1 | c.567C>T p.V189= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs1238539010, COSV68012559; called by muse, mutect2, varscan2
- OAZ3 | c.372C>T p.H124= | Silent (SNP) | VAF 63/154 reads (41%) | catalogued as rs1202299325, COSV58618033; called by muse, mutect2, varscan2
- OGDH | c.2313G>C p.R771= | Silent (SNP) | VAF 9/171 reads (5%) | catalogued as COSV56048808, COSV56055389; called by muse, mutect2
- OLFML2B | c.1599T>C p.Y533= | Silent (SNP) | VAF 86/492 reads (17%) | catalogued as COSV54195857; called by muse, mutect2, varscan2
- OR4Q3 | c.213T>C p.F71= | Silent (SNP) | VAF 65/220 reads (30%) | catalogued as COSV59178363; called by muse, mutect2, varscan2
- PIP4K2C | c.99C>T p.F33= | Silent (SNP) | VAF 115/404 reads (28%) | catalogued as rs1312390710, COSV61606022; called by muse, mutect2, varscan2
- REXO1 | c.996C>T p.G332= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs779792117, COSV50076881; called by muse, mutect2, varscan2
- ROBO2 | c.2877C>A p.G959= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs763417919, COSV59907888; called by muse, mutect2, varscan2
- RXFP4 | c.834C>T p.P278= | Silent (SNP) | VAF 181/399 reads (45%) | catalogued as COSV58144282; called by muse, mutect2, varscan2
- SERPINF1 | c.1221C>G p.L407= | Silent (SNP) | VAF 32/250 reads (13%) | catalogued as COSV54616003; called by muse, mutect2, varscan2
- SETDB1 | c.729G>A p.S243= | Silent (SNP) | VAF 21/306 reads (7%) | catalogued as COSV54981178, COSV54985251; called by muse, mutect2
- SLC17A2 | c.375T>A p.G125= | Silent (SNP) | VAF 20/155 reads (13%) | catalogued as COSV55351608; called by muse, mutect2, varscan2
- SLC26A11 | c.18G>C p.T6= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs1349338618, COSV58339094; called by muse, mutect2, varscan2
- SLC2A10 | c.960C>A p.A320= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV63714332; called by muse, mutect2, varscan2
- SLC34A2 | c.1518G>A p.P506= | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as rs1016233086, COSV65941333; called by muse, mutect2, varscan2
- SPAST | c.942G>A p.L314= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs776121105, COSV59514007; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPATA5 | c.930A>G p.L310= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs141742510, COSV56774906; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPG11 | c.504C>T p.I168= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV55993703; called by muse, mutect2, varscan2
- SPTAN1 | c.3261G>A p.L1087= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as COSV63986656; called by muse, varscan2
- STAMBPL1 | c.444C>G p.L148= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV64222453; called by muse, mutect2, varscan2
- STX11 | c.681C>G p.L227= | Silent (SNP) | VAF 43/71 reads (61%) | catalogued as COSV62449010; called by muse, mutect2, varscan2
- TAS2R39 | c.138C>A p.L46= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV71470865; called by muse, mutect2, varscan2
- TMEM179B | c.633C>T p.L211= | Silent (SNP) | VAF 65/177 reads (37%) | catalogued as rs1565194313, COSV53668161; called by muse, mutect2, varscan2
- TRIP6 | c.1116C>T p.L372= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as rs1271553342, COSV52341618; called by muse, mutect2, varscan2
- TTC39B | c.1407G>A p.V469= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as rs1375741508, COSV52609728; called by muse, mutect2, varscan2
- UROC1 | c.1623G>A p.L541= | Silent (SNP) | VAF 93/254 reads (37%) | catalogued as COSV52031929; called by muse, mutect2, varscan2
- VWA7 | c.2418G>C p.V806= | Silent (SNP) | VAF 26/531 reads (5%) | catalogued as COSV65173051; called by muse, mutect2
- WFDC8 | c.516C>T p.D172= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV51489361; called by muse, mutect2
- ZC3H6 | c.3156G>A p.R1052= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV59667268; called by muse, mutect2, varscan2
- ZC3HAV1 | c.993A>G p.L331= | Silent (SNP) | VAF 64/139 reads (46%) | catalogued as rs1340330320, COSV54295144; called by muse, mutect2, varscan2
- ZNF184 | c.186A>T p.T62= | Silent (SNP) | VAF 13/160 reads (8%) | catalogued as COSV53004055; called by muse, mutect2
- ZNF445 | c.1086G>A p.K362= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV68538779; called by muse, mutect2, varscan2
- ZNF551 | c.489G>A p.K163= | Silent (SNP) | VAF 119/215 reads (55%) | catalogued as rs778592998, COSV56592406; called by muse, mutect2, varscan2
- ZNF555 | c.447A>G p.G149= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV62073101; called by muse, mutect2
- AP000769.3 | chr11:65505147 G>T | 5'Flank (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- CPLANE1 | chr5:37169033 C>T | 3'Flank (SNP) | VAF 57/160 reads (36%) | catalogued as COSV57058005; called by muse, mutect2, varscan2
- GATB | c.*1G>C | 3'UTR (SNP) | VAF 61/140 reads (44%) | catalogued as COSV99859023; called by muse, mutect2, varscan2
- LINC02145 | n.105G>A | RNA (SNP) | VAF 22/243 reads (9%) | catalogued as rs1286699708; called by muse, mutect2
- SPEN | c.404+1052C>G | Intron (SNP) | VAF 18/72 reads (25%) | catalogued as COSV65360885; called by muse, varscan2
- SPEN | c.404+1129C>G | Intron (SNP) | VAF 20/123 reads (16%) | catalogued as COSV65360888; called by muse, varscan2
- TTLL3 | c.745-1557G>A | Intron (SNP) | VAF 10/24 reads (42%) | catalogued as rs774275651, COSV59616540; called by muse, varscan2
